Gene-level copy-number profile of tumor specimen TCGA-77-6845-01A from TCGA case TCGA-77-6845, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.3 years (25,321 days).
Specimen TCGA-77-6845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2d39c891-ae47-419e-b85c-22caf888c296.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-6845-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94c25c6b-fc14-4f40-8822-518ce307019c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,190; copy number 2: 17,206; copy number 3: 14,775; copy number 4: 14,559; copy number 5: 4,169; copy number 6: 4,255; copy number 7: 2,558; copy number 8: 116; copy number 9: 447; copy number 10: 231; copy number 11: 19; copy number 13: 126; copy number 17: 45; copy number 23: 75; copy number 26: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-6845-01A-11D-1943-01): tumor purity 0.78, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12,080 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,466,937–41,484,683, 2 genes, copy number 5: RNA5SP45, EDN2.
- chr1:41,535,443–41,628,816, 3 genes, copy number 5: AL445933.2, AL445933.1, AC119676.1.
- chr1:151,399,560–176,845,601, 837 genes, copy number 5 (broad region; genes not listed).
- chr1:181,190,471–182,830,384, 32 genes, copy number 5: AL358393.1, LINC01699, CACNA1E, Metazoa_SRP, RNA5SP70, AL161734.2, AL161734.1, RN7SKP229, AL391477.1, ZNF648, AL355482.1, AL355482.2, LINC01344, AL390856.1, YPEL5P1, RNU6-152P, AL513480.1, EIF1P3, GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL.
- chr1:219,608,010–248,919,946, 707 genes, copy number 6–9 (broad region; genes not listed).
- chr2:38,814–59,063,766, 934 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr3:171,058,414–186,362,234, 260 genes, copy number 7–23 (within-gene range 4–23) (broad region; genes not listed).
- chr4:16,226,685–17,073,903, 10 genes, copy number 5: TAPT1-AS1, RPS21P4, AC006427.1, AC006427.2, ZEB2P1, AC097515.1, LDB2, AC104656.1, AC106894.1, MTND5P4.
- chr4:163,524,298–164,384,050, 1 gene, copy number 6 (within-gene range 3–6): MARCHF1.
- chr4:163,828,800–166,104,457, 43 genes, copy number 6 (within-gene range 3–6): RN7SKP105, YWHAQP4, AC105250.1, ANP32C, AC074198.1, RNU6-284P, CHORDC1P3, SMIM31, RNU6-668P, APELA, TRIM60P14, AC106872.3, AC106872.12, FAM218BP, AC106872.10, AC106872.5, NACA3P, AC106872.1, TRIM61, FAM218A, AC106872.4, AC106872.9, AC106872.8, AC106872.2, TRIM60, AC106872.11, AC106872.7, AC106872.6, TRIM75P, TMEM192, KLHL2, RNU4-87P, GK3P, MSMO1, CPE, MIR578, HADHAP1, SCGB1D5P, NOL8P1, AC080079.2, AC080079.1, LINC01179, TLL1.
- chr4:168,828,919–171,638,763, 41 genes, copy number 5: AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1, HSP90AA6P, LINC02382, AC097486.1, RNU6ATAC13P, AC034159.2, LINC02431, AC034159.1, AC092639.1, MIR6082, LINC02504, AC074254.2, LINC02174, AC074254.1.
- chr5:58,198–23,305,143, 379 genes, copy number 7–10 (broad region; genes not listed).
- chr6:41,026,895–46,207,386, 164 genes, copy number 5 (broad region; genes not listed).
- chr7:996,986–159,233,377, 2,986 genes, copy number 5–9 (broad region; genes not listed).
- chr8:64,331,927–81,112,068, 260 genes, copy number 6–13 (within-gene range 3–13) (broad region; genes not listed).
- chr10:34,663,859–43,483,181, 130 genes, copy number 5–26 (broad region; genes not listed).
- chr10:80,529,597–81,137,335, 8 genes, copy number 5: AC021028.1, SH2D4B, LINC02655, RPS7P9, AC027673.1, FARSBP1, WARS2P1, RPA2P2.
- chr11:68,312,591–135,075,908, 1,421 genes, copy number 7 (broad region; genes not listed).
- chr13:47,307,082–68,331,613, 252 genes, copy number 6 (broad region; genes not listed).
- chr14:71,320,449–71,741,229, 1 gene, copy number 7 (within-gene range 4–7): SIPA1L1.
- chr14:71,448,689–88,036,319, 277 genes, copy number 7 (broad region; genes not listed).
- chr14:95,181,940–95,319,908, 1 gene, copy number 6 (within-gene range 4–6): CLMN.
- chr14:95,319,483–106,875,071, 585 genes, copy number 6–9 (broad region; genes not listed).
- chr15:68,054,309–73,368,958, 116 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr18:508,568–2,655,395, 46 genes, copy number 6–11: LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2.
- chr18:3,496,032–4,455,307, 1 gene, copy number 7 (within-gene range 2–7): DLGAP1.
- chr18:3,894,699–24,453,531, 364 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr19:27,638,483–30,228,715, 63 genes, copy number 6–9 (broad region; genes not listed).
- chr19:31,797,666–41,930,150, 489 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr20:87,250–16,983,033, 312 genes, copy number 6 (broad region; genes not listed).
- chr20:21,114,723–23,550,652, 66 genes, copy number 5 (broad region; genes not listed).
- chr21:10,328,411–19,345,312, 134 genes, copy number 5–7 (broad region; genes not listed).
- chr21:25,031,005–27,751,233, 46 genes, copy number 7: AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113.
- chr22:17,787,649–18,024,561, 1 gene, copy number 6 (within-gene range 4–6): MICAL3.
- chr22:17,980,868–44,572,453, 1,108 genes, copy number 5–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 651. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
